CCDI case PBBLWR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e9ba2653-ab5b-4c17-a5cf-6972d6f516ea

Demographics
Sex at birth: female; Race: asian; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 9.4 years (3,444 days).

Biospecimens (3 samples)
- Sample 0DD53G: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DD53K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DD5SA: Tissue type: Tumor; Specimen type: Solid Tissue.
